Surgical pathology report (de-identified scan), TCGA case TCGA-HS-A5N8, project TCGA-SARC (Sarcoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HS-A5N8-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Leiomyosarcoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Uterus, Ovary
Tumour Size (cm)	10
Histology	Leiomyosarcoma
Grade/Differentiation	X
Pathological T	T2b
Pathological N	NX
Clinical M	M0
Histology Comments	

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

IED-0-3

Leiomyosarcoma NOS 8890/3
Site: Uterus NOS C55.9

JW 2/11/13

Criteria	JW 2/11/13	Yes	No

Source: NCI Genomic Data Commons file 6ec4169a-9e24-41fc-9667-4853a3cbc0da (TCGA-HS-A5N8.23C57E99-5BF2-4CD2-AC62-E58D3FBBF273.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).